Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PU, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PU-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, tubular 8211/3
Site: Body of stomach C16.2
3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "Stomach + spleen + pancreas tail + small intestine":

Adenocarcinoma:

Histological pattern observed: tubular

Histological grade:

III - poorly differentiated.

Measure of the longest axis of the tumor: 11.5 cm

Ulceration: present

Involvement of:

Mucosa

Muscularis mucosae

Submucosa

Muscularis propria

Adjacent adipose tissue

Other structures: pancreas

Type of tumor invasion: spiculated

Inflammatory reaction: moderate

Tumor implantation in perivisceral adipose tissue: not detected

Proximal and distal margins: absence of neoplastic involvement.

Neural infiltration: not detected

Lymphatic vascular invasion: present

Blood vascular invasion: not detected

Lymph nodes:

Involved: 1/6

Capsular transposition: not detected

Ratio of involved/dissected lymph nodes: 1/6

Conglomerated lymph nodes: not detected

Greater omentum: absence of neoplastic involvement

Spleen: absence of neoplastic involvement

Note: Lauren's classification - intestinal pattern.

2 - "Duodenal margin": Absence of neoplastic involvement.

3 - "Lymph node 8A": Lymph node uninvolved by neoplasia (0/3).

4 - "Esophageal margin": Absence of neoplastic involvement.

Primary Tumor Site Inaccuracy		☒
ICD-O Discrepancy		☒
Site Malignancy History	☒	☒

Source: NCI Genomic Data Commons file dd78ee43-932f-4ce9-a28e-1958a0c2a356 (TCGA-VQ-A8PU.B3E4F95C-B684-4B3B-857F-BE164A289051.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).